Somatic mutation profile of tumor specimen C3L-04391-02 (aliquot CPT0234560006) from CPTAC case C3L-04391, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 70.2 years (25,641 days).
Specimen C3L-04391-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8247b0d-b257-4159-a0a0-299018d00ed6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04391-31 (Blood Derived Normal), aliquot CPT0235180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21336489-dd94-43b4-9edd-82b2319096a8

The open-access MAF lists 258 somatic variants for this specimen: 186 protein-altering or splice-affecting, 42 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 42, Intron 17, Nonsense Mutation 9, Frame Shift Del 7, RNA 6, Splice Site 4, 5'UTR 2, Translation Start Site 2, Splice Region 2, 3'Flank 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.827C>G p.A276G | Missense Mutation (SNP) | VAF 206/673 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs786202082, CD098502, COSV52704969, COSV52749634, COSV52761908, COSV52834111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOB | c.4514G>T p.C1505F | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV99266053; called by muse, mutect2, varscan2
- APOL6 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs200170835; called by muse, mutect2
- ARMCX2 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 108/217 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.012); catalogued as COSV100168178; called by muse, mutect2, varscan2
- ARSG | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV71593584; called by muse, mutect2, varscan2
- ATAT1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1198681934; called by muse, mutect2, varscan2
- ATF7IP | c.620G>T p.S207I | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs893227971, COSV53773964; called by muse, mutect2, varscan2
- CALB2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 115/208 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs1375850883, COSV56940903; called by muse, mutect2, varscan2
- CATSPERE | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs899435702; called by muse, mutect2
- CCDC185 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.808); catalogued as rs573008518, COSV64822148; called by muse, mutect2, varscan2
- CNTNAP2 | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 36/278 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV62226848; called by muse, mutect2, varscan2
- COL4A4 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631839; called by muse, mutect2, varscan2
- CPS1 | c.3337-1G>T p.X1113_splice | Splice Site (SNP) | VAF 17/138 reads (12%) | catalogued as CS114435, COSV99241977; called by muse, mutect2, varscan2
- CSMD3 | c.8367C>G p.F2789L (on ENST00000297405 / NM_001363185.1; = p.F2620L on NM_052900.3) | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV52204322; called by muse, mutect2
- CTNND2 | c.2722G>A p.V908M | Missense Mutation (SNP) | VAF 109/467 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58882274; called by muse, mutect2, varscan2
- DCDC1 | c.4555G>C p.D1519H (on ENST00000597505 / NM_001367979.1; = p.D626H on NM_020869.3) | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV104410468; called by muse, mutect2
- DNAH5 | c.5053C>G p.L1685V | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54243110; called by muse, mutect2
- DPP4 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1284790925, COSV62107503; called by muse, mutect2, varscan2
- EFHB | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV99860446; called by muse, mutect2, varscan2
- FAM135B | c.3449G>T p.G1150V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52756291; called by muse, mutect2, varscan2
- FAM135B | c.3449-1G>T p.X1150_splice | Splice Site (SNP) | VAF 18/126 reads (14%) | catalogued as COSV52759047; called by muse, mutect2, varscan2
- FH | c.738+1G>T p.X246_splice | Splice Site (SNP) | VAF 47/242 reads (19%) | catalogued as COSV63819288; called by muse, mutect2, varscan2
- FSIP2 | c.19778G>A p.R6593K | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV100554828; called by mutect2, varscan2
- GALNT11 | c.867del p.V290Sfs*21 | Frame Shift Del (DEL) | VAF 32/316 reads (10%) | catalogued as COSV57427703; called by mutect2, pindel, varscan2
- GRM1 | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 54/498 reads (11%) | catalogued as COSV51162177; called by muse, varscan2
- HCK | c.608T>C p.L203P | Missense Mutation (SNP) | VAF 80/420 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751576419; called by muse, mutect2, varscan2
- HCN1 | c.881C>A p.A294E | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100298037; called by muse, mutect2, varscan2
- HECW1 | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs746649044; called by muse, mutect2, varscan2
- IGKV1D-16 | c.330C>A p.C110* | Nonsense Mutation (SNP) | VAF 79/503 reads (16%) | catalogued as rs758557083; called by muse, mutect2, varscan2
- IGKV1D-16 | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 78/495 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs777668997; called by muse, mutect2, varscan2
- IRF1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV55376120; called by muse, mutect2
- KARS1 | c.1342G>C p.V448L | Missense Mutation (SNP) | VAF 49/459 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs759047321, COSV56690546; called by muse, mutect2, varscan2
- KCNJ12 | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782232946; called by muse, mutect2, varscan2
- KLHL9 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV62922208; called by muse, mutect2
- KLRF1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1288788111, COSV54382265; called by muse, mutect2, varscan2
- LAPTM4B | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1376613965, COSV63393064; called by muse, mutect2
- LMO7 | c.719C>G p.S240W (on ENST00000357063; = p.S255W on NM_005358.5) | Missense Mutation (SNP) | VAF 99/338 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58531619; called by muse, mutect2, varscan2
- MBL2 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64759306; called by muse, mutect2, varscan2
- MMP2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 174/562 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.43); catalogued as rs545385578; called by muse, mutect2, varscan2
- MTX2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 30/132 reads (23%) | catalogued as rs538690042; called by muse, mutect2, varscan2
- NAB2 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1375108249; called by muse, mutect2
- NOS3 | c.2984G>A p.G995E | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV52490684; called by muse, mutect2, varscan2
- OR2A25 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 59/519 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770933489; called by muse, mutect2, varscan2
- PAPPA2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 34/317 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs770493671, COSV100866600, COSV62776460; called by muse, mutect2, varscan2
- PDE3A | c.3198C>A p.F1066L | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.108); catalogued as COSV62977213; called by muse, mutect2, varscan2
- PIWIL1 | c.153del p.Q52Rfs*25 | Frame Shift Del (DEL) | VAF 21/191 reads (11%) | catalogued as COSV99806619; called by mutect2, pindel, varscan2
- PPL | c.2729A>T p.E910V | Missense Mutation (SNP) | VAF 66/420 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99277459; called by muse, mutect2, varscan2
- PRAMEF1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 73/671 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as rs762671268; called by muse, mutect2, varscan2
- PRKCH | c.412G>C p.G138R | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.135); catalogued as COSV99076016; called by muse, mutect2, varscan2
- PTPRM | c.1726A>G p.T576A | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV59880513, COSV59885286; called by muse, mutect2, varscan2
- PTPRZ1 | c.2893G>T p.G965C | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.366); catalogued as rs142021602, COSV101099955; called by muse, mutect2
- RGS7 | c.884C>A p.P295Q | Missense Mutation (SNP) | VAF 60/310 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58547558, COSV58555678; called by muse, mutect2, varscan2
- ROCK1 | c.1827A>G p.I609M | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1198594955; called by muse, mutect2, varscan2
- RRBP1 | c.2716G>T p.E906* (on ENST00000377813 / NM_001365613.2; = p.E473* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 22/217 reads (10%) | catalogued as COSV55701993; called by muse, mutect2, varscan2
- SIMC1 | c.505A>G p.T169A (on ENST00000443967 / NM_001308196.1; = p.T188A on NM_001308195.2) | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs760832634; called by muse, mutect2, varscan2
- SLITRK2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV59425285; called by muse, mutect2, varscan2
- SYNM | c.3697G>C p.E1233Q | Missense Mutation (SNP) | VAF 37/488 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV50442714; called by muse, mutect2
- SYNPO2 | c.2840C>A p.P947H | Missense Mutation (SNP) | VAF 72/403 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1165201613; called by muse, mutect2, varscan2
- TENM1 | c.5845G>C p.D1949H | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100949654; called by muse, mutect2
- TFAP2B | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 63/378 reads (17%) | catalogued as rs1474152110, COSV53830211; called by muse, mutect2, varscan2
- TNN | c.2275C>A p.Q759K | Missense Mutation (SNP) | VAF 62/625 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs747746975, COSV53437445; called by muse, mutect2
- TRAPPC12 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); catalogued as rs372611768; called by muse, mutect2, varscan2
- TRPV5 | c.1039T>C p.C347R | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54686910; called by muse, mutect2, varscan2
- TTN | c.1766C>T p.T589I | Missense Mutation (SNP) | VAF 238/464 reads (51%) | PolyPhen benign (0); catalogued as rs768848011; called by muse, mutect2, varscan2
- UGT3A2 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV56934102; called by muse, mutect2, varscan2
- VWA3B | c.1993G>T p.D665Y | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV68241218, COSV68243853; called by muse, mutect2, varscan2
- XIRP2 | c.7395G>C p.K2465N (on ENST00000628543; = p.K2640N on NM_152381.6) | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1165838926, COSV54694403; called by muse, mutect2
- YEATS2 | c.3524C>T p.S1175F | Missense Mutation (SNP) | VAF 57/494 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1015632551, COSV59364056; called by muse, mutect2, varscan2
- ZAN | c.4148T>C p.L1383P | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.281); catalogued as rs1229796091; called by muse, mutect2
- ZNF671 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs376994504; called by muse, mutect2, varscan2
- AASDH | c.2857A>G p.I953V | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.038); called by muse, mutect2
- ABCG8 | c.1651G>T p.A551S | Missense Mutation (SNP) | VAF 38/790 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.942); called by muse, mutect2
- AFF3 | c.1271C>A p.S424Y | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AGBL3 | c.1527T>A p.N509K | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AIFM3 | c.1297A>G p.T433A | Missense Mutation (SNP) | VAF 159/461 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- AMER3 | c.2029G>T p.V677L | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- ANKS1A | c.3224G>A p.G1075D | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- ATF7 | c.1069G>A p.A357T (on ENST00000548446 / NM_001366555.2; = p.A346T on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/509 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP2B3 | c.3438G>T p.E1146D | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- BAG5 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- BAG5 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 70/222 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- BAZ2B | c.6188C>G p.S2063C | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2CD4C | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD5 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- C2CD6 | c.1369G>C p.G457R | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C5orf52 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.136); called by muse, mutect2
- C6 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CCDC34 | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CDHR3 | c.1513A>T p.S505C | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CELF4 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CHDH | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CIC | c.3862G>T p.E1288* | Nonsense Mutation (SNP) | VAF 134/399 reads (34%) | called by muse, mutect2, varscan2
- COL1A2 | c.3605C>T p.T1202I | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- COL4A4 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.3709G>A p.G1237R | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.757); called by muse, mutect2
- COPS2 | c.537C>G p.C179W | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUX2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DAPK3 | c.721T>G p.F241V | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.2926C>G p.Q976E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DPH7 | c.375+5G>T | Splice Region (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- DRP2 | c.2509G>T p.A837S | Missense Mutation (SNP) | VAF 125/333 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- EIF3A | c.3334G>T p.G1112W | Missense Mutation (SNP) | VAF 81/663 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); called by muse, varscan2
- EPHB3 | c.2903T>A p.I968N | Missense Mutation (SNP) | VAF 19/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- EPS8L3 | c.1555C>G p.P519A (on ENST00000361965 / NM_133181.4; = p.P489A on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ERVH48-1 | c.362A>T p.N121I | Missense Mutation (SNP) | VAF 50/394 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EVC | c.420T>A p.H140Q | Missense Mutation (SNP) | VAF 58/439 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- EXT2 | c.2T>C p.M1? (on ENST00000343631; = p.M34T on NM_000401.3) | Translation Start Site (SNP) | VAF 30/92 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); called by muse, mutect2
- FAM161A | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- FANCL | c.167G>T p.S56I | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FAT4 | c.14259G>T p.R4753S | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2
- FMN2 | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 26/568 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2
- FSD1 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FSD1 | c.490+5G>C | Splice Region (SNP) | VAF 28/114 reads (25%) | called by muse, mutect2, varscan2
- FSIP2 | c.9188A>C p.N3063T | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GBP7 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- GFRA2 | c.965G>T p.W322L | Missense Mutation (SNP) | VAF 109/297 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GGT5 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.232); called by muse, mutect2
- GIPC2 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- GLIS1 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GUCY2F | c.896G>C p.R299T | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.017); called by muse, mutect2
- HDLBP | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 27/298 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.09); called by muse, mutect2
- HTR1A | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HTR1A | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO13 | c.719A>T p.E240V | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ITGB2 | c.1195C>A p.P399T (on ENST00000302347; = p.P375T on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/501 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- JAKMIP2 | c.2372C>A p.T791K | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- KHDRBS2 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.338); called by muse, mutect2
- KIAA1671 | c.1924C>G p.H642D | Missense Mutation (SNP) | VAF 48/741 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIF19 | c.1503C>A p.D501E | Missense Mutation (SNP) | VAF 177/526 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.8266C>G p.L2756V | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LAMC3 | c.648del p.Y217Tfs*22 | Frame Shift Del (DEL) | VAF 44/171 reads (26%) | called by mutect2, pindel
- LRRK2 | c.4481C>T p.S1494F | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- MAGEA8 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- MAGEB4 | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2
- MAST4 | c.1339G>C p.D447H (on ENST00000403625 / NM_001164664.2; = p.D258H on NM_015183.3) | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEP1A | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MROH1 | c.3008G>A p.G1003D | Missense Mutation (SNP) | VAF 50/522 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRPL1 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MRRF | c.788G>T p.*263Lext*44 | Nonstop Mutation (SNP) | VAF 91/396 reads (23%) | called by muse, mutect2, varscan2
- MS4A8 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MTERF3 | c.711_712delinsT p.K237Nfs*15 | Frame Shift Del (DEL) | VAF 13/97 reads (13%) | called by pindel, varscan2*
- NBAS | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 23/570 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2
- NCKAP5 | c.4795A>T p.K1599* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | called by muse, varscan2
- NDN | c.35A>C p.N12T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKX6-3 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 89/241 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NOTCH1 | c.971_977del p.V324Afs*305 | Frame Shift Del (DEL) | VAF 155/575 reads (27%) | called by mutect2, pindel, varscan2
- NPHS2 | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 30/402 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- NT5C | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NT5C1A | c.998A>T p.H333L | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NTRK3 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OAF | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 95/745 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODF2L | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR14J1 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR1L4 | c.478C>A p.R160S | Missense Mutation (SNP) | VAF 90/498 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, varscan2
- OR8K5 | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- OSBPL9 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PLPPR4 | c.1865G>A p.R622K | Missense Mutation (SNP) | VAF 15/297 reads (5%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.695); called by muse, mutect2
- PRR30 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 113/450 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PTCHD3 | c.2059G>A p.V687I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.133); called by muse, mutect2
- PTCHD4 | c.794G>C p.G265A | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- PUM2 | c.1597T>G p.S533A | Missense Mutation (SNP) | VAF 102/362 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- RASSF3 | c.470del p.K157Sfs*14 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | called by mutect2, pindel, varscan2
- REG1B | c.448A>C p.K150Q | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- RIMS1 | c.3275C>A p.T1092K | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCGB3A1 | c.189C>G p.S63R | Missense Mutation (SNP) | VAF 95/390 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- SETMAR | c.2024G>A p.C675Y | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.868); called by muse, mutect2
- SLC12A4 | c.2033T>A p.L678* | Nonsense Mutation (SNP) | VAF 16/338 reads (5%) | called by muse, mutect2
- SLCO1A2 | c.1246G>T p.V416F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.317); called by muse, mutect2
- SMAD4 | c.1378_1390del p.A460Pfs*12 | Frame Shift Del (DEL) | VAF 24/190 reads (13%) | called by mutect2, pindel
- TCN1 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TDRKH | c.1559T>C p.L520P | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- THSD7B | c.4500G>C p.E1500D (on ENST00000272643; = p.E1498D on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMPRSS15 | c.2885G>A p.G962E | Missense Mutation (SNP) | VAF 49/204 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.57076G>C p.D19026H (on ENST00000591111; = p.D11602H on NM_003319.4) | Missense Mutation (SNP) | VAF 111/256 reads (43%) | PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- TUBB8 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 58/993 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- TUT7 | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UGT3A2 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 41/212 reads (19%) | called by muse, mutect2, varscan2
- USH2A | c.12007C>A p.Q4003K | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- USH2A | c.9715G>C p.G3239R | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- XPO1 | c.10A>G p.I4V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- YDJC | c.461A>G p.Y154C | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- YTHDF3 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- ZDBF2 | c.6101G>T p.S2034I | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ZFHX4 | c.8467A>G p.M2823V | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2
- ZNF341 | c.1184C>G p.A395G (on ENST00000375200 / NM_001282935.1; = p.A388G on NM_032819.4) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ZSCAN5B | c.911C>A p.S304Y | Missense Mutation (SNP) | VAF 62/486 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ADA2 | c.1161T>A p.A387= (on ENST00000262607; = p.A146= on NM_177405.3) | Silent (SNP) | VAF 32/314 reads (10%) | called by muse, mutect2, varscan2
- ADAM21 | c.1053T>C p.H351= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- ADARB2 | c.282C>A p.P94= | Silent (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- ANKS6 | c.1641C>T p.T547= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- ARSD | c.570C>G p.P190= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as rs73632974, COSV54198275; called by muse, mutect2, varscan2
- ART4 | c.786A>T p.P262= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- BAZ1A | c.2055A>G p.K685= | Silent (SNP) | VAF 24/195 reads (12%) | called by muse, mutect2, varscan2
- BCL7C | c.537A>C p.G179= | Silent (SNP) | VAF 29/98 reads (30%) | called by muse, mutect2, varscan2
- BIN1 | c.228C>T p.H76= | Silent (SNP) | VAF 72/538 reads (13%) | catalogued as rs754621895; called by muse, mutect2, varscan2
- CCND3 | c.705T>G p.T235= | Silent (SNP) | VAF 65/222 reads (29%) | catalogued as COSV57828613; called by muse, mutect2, varscan2
- CLDN6 | c.135G>A p.V45= | Silent (SNP) | VAF 22/594 reads (4%) | catalogued as COSV58509577; called by muse, mutect2
- COL28A1 | c.3192G>A p.V1064= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- CPSF1 | c.453C>T p.A151= | Silent (SNP) | VAF 18/272 reads (7%) | catalogued as rs782553256; called by muse, mutect2
- CREB3L1 | c.1248G>T p.T416= | Silent (SNP) | VAF 55/181 reads (30%) | catalogued as COSV55830603; called by muse, mutect2, varscan2
- DDX58 | c.180C>T p.F60= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- GIGYF2 | c.66G>T p.G22= | Silent (SNP) | VAF 30/203 reads (15%) | called by muse, mutect2, varscan2
- KCNH6 | c.153C>G p.L51= | Silent (SNP) | VAF 90/555 reads (16%) | called by muse, mutect2, varscan2
- LPAR2 | c.486G>T p.G162= | Silent (SNP) | VAF 56/356 reads (16%) | called by muse, mutect2, varscan2
- MAP2K3 | c.195G>A p.V65= (on ENST00000342679 / NM_145109.3; = p.V36= on NM_002756.4) | Silent (SNP) | VAF 28/406 reads (7%) | called by muse, mutect2
- MAP3K7 | c.1695T>C p.S565= (on ENST00000369329 / NM_145331.3; = p.S538= on NM_003188.4) | Silent (SNP) | VAF 52/169 reads (31%) | called by muse, mutect2, varscan2
- MDGA2 | c.1782G>A p.V594= (on ENST00000399232 / NM_001113498.2; = p.V296= on NM_182830.4) | Silent (SNP) | VAF 34/79 reads (43%) | called by muse, varscan2
- MLIP | c.591C>A p.A197= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99230733; called by muse, mutect2, varscan2
- MRGPRG | c.609G>A p.A203= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs1407431621; called by muse, mutect2
- OR2B11 | c.102C>A p.V34= | Silent (SNP) | VAF 32/394 reads (8%) | catalogued as rs569011284, COSV100276151; called by muse, mutect2
- OR2M7 | c.543C>T p.F181= | Silent (SNP) | VAF 78/329 reads (24%) | catalogued as rs1018570549; called by muse, mutect2, varscan2
- OTX1 | c.504G>A p.L168= | Silent (SNP) | VAF 127/502 reads (25%) | called by muse, mutect2, varscan2
- PDCD6IP | c.519A>G p.R173= | Silent (SNP) | VAF 77/290 reads (27%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1783C>A p.R595= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1170384173; called by muse, mutect2, varscan2
- PPP6R1 | c.741G>T p.T247= | Silent (SNP) | VAF 70/207 reads (34%) | called by muse, mutect2, varscan2
- PRR19 | c.144C>T p.A48= | Silent (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
- RACGAP1 | c.1365A>T p.I455= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- RNF32 | c.264G>A p.P88= | Silent (SNP) | VAF 27/225 reads (12%) | catalogued as rs199882571, COSV58735244; called by muse, mutect2, varscan2
- S1PR2 | c.81G>T p.T27= | Silent (SNP) | VAF 73/224 reads (33%) | called by muse, mutect2, varscan2
- SUN2 | c.486G>A p.A162= | Silent (SNP) | VAF 29/214 reads (14%) | catalogued as rs758870911, COSV99325736; called by muse, mutect2, varscan2
- TAF1L | c.3627C>A p.V1209= | Silent (SNP) | VAF 107/369 reads (29%) | catalogued as COSV54262208; called by muse, mutect2, varscan2
- TAOK2 | c.849G>C p.R283= | Silent (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- TNRC6B | c.1788A>T p.T596= | Silent (SNP) | VAF 65/229 reads (28%) | called by muse, mutect2, varscan2
- TRIP12 | c.5565G>A p.Q1855= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as rs1162657198; called by muse, mutect2, varscan2
- WDR72 | c.1119C>T p.A373= | Silent (SNP) | VAF 50/229 reads (22%) | catalogued as rs1161077093; called by muse, mutect2, varscan2
- XKR4 | c.1782C>A p.V594= | Silent (SNP) | VAF 26/212 reads (12%) | called by muse, mutect2, varscan2
- ZC3HAV1 | c.1566G>A p.P522= | Silent (SNP) | VAF 16/211 reads (8%) | catalogued as rs754382116; called by muse, mutect2
- ZMYM3 | c.3855G>A p.Q1285= | Silent (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- AIPL1 | c.785-22G>A | Intron (SNP) | VAF 51/154 reads (33%) | catalogued as COSV100005962; called by muse, mutect2, varscan2
- AL033381.1 | n.245C>G | RNA (SNP) | VAF 66/201 reads (33%) | called by muse, mutect2, varscan2
- AL035696.1 | n.372C>G | RNA (SNP) | VAF 23/272 reads (8%) | called by muse, mutect2
- CENPT | c.201+46G>A | Intron (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- CLVS1 | c.-152+55C>A | Intron (SNP) | VAF 64/392 reads (16%) | called by muse, mutect2, varscan2
- EEF1A2 | c.*19G>T | 3'UTR (SNP) | VAF 39/158 reads (25%) | called by muse, varscan2
- EEF1B2 | c.-10A>G | 5'UTR (SNP) | VAF 16/104 reads (15%) | catalogued as rs1277734076; called by muse, mutect2, varscan2
- ERBB4 | c.82+112161C>A | Intron (SNP) | VAF 8/69 reads (12%) | called by mutect2, varscan2
- ERBB4 | c.82+112160A>T | Intron (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- HDAC6 | c.999+16G>C | Intron (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- HSP90AB3P | n.749C>G | RNA (SNP) | VAF 39/201 reads (19%) | called by muse, mutect2, varscan2
- LHX9 | c.-323C>T | 5'UTR (SNP) | VAF 28/343 reads (8%) | called by muse, mutect2
- MUCL3 | c.946+126C>T | Intron (SNP) | VAF 120/522 reads (23%) | called by muse, mutect2, varscan2
- NOL4L | c.*334C>T | 3'UTR (SNP) | VAF 45/224 reads (20%) | catalogued as rs148425684; called by muse, mutect2, varscan2
- NPC1 | c.2795+21T>C | Intron (SNP) | VAF 39/310 reads (13%) | called by muse, mutect2, varscan2
- NSMCE2 | c.158-20921C>G | Intron (SNP) | VAF 18/221 reads (8%) | called by muse, mutect2
- PHETA1 | chr12:111365598 A>G | 5'Flank (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- POM121L9P | n.1410C>A | RNA (SNP) | VAF 34/900 reads (4%) | called by muse, mutect2
- PRKAG2 | c.115-20930G>C | Intron (SNP) | VAF 24/393 reads (6%) | called by muse, mutect2
- SIRT2 | c.376-16G>T | Intron (SNP) | VAF 80/200 reads (40%) | called by muse, mutect2, varscan2
- SNORD109A | chr15:25042049 G>A | 3'Flank (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.426A>G | RNA (SNP) | VAF 134/471 reads (28%) | called by muse, mutect2, varscan2
- TBL2 | c.130+170G>T | Intron (SNP) | VAF 42/213 reads (20%) | called by muse, mutect2, varscan2
- TBXAS1 | c.451-720G>T | Intron (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- TPSAB1 | c.1-31C>A | Intron (SNP) | VAF 41/187 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.10360+4048G>T | Intron (SNP) | VAF 12/153 reads (8%) | catalogued as COSV60215540; called by muse, mutect2
- TUBB7P | n.394G>T | RNA (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- VIM | c.720+12G>A | Intron (SNP) | VAF 34/642 reads (5%) | called by muse, mutect2
- VSIG4 | chrX:66018965 G>T | 3'Flank (SNP) | VAF 77/195 reads (39%) | called by muse, mutect2, varscan2
- WDR72 | c.857+18C>T | Intron (SNP) | VAF 43/370 reads (12%) | catalogued as rs370920198, COSV100854300; called by muse, mutect2, varscan2
